Somatic mutation profile of tumor specimen MP2PRT-PAVUYA-TMP1-A (aliquot MP2PRT-PAVUYA-TMP1-A-1-0-D-A81A-36) from MP2PRT case MP2PRT-PAVUYA, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.3 years (1,572 days).
Specimen MP2PRT-PAVUYA-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d0e1b866-f9b0-4a19-b4c5-629e10d45a6c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVUYA-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVUYA-NB1-A-1-0-D-A81A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7c283f9c-c064-4f5f-b21c-e5f2100976bf

The open-access MAF lists 21 somatic variants for this specimen: 17 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 3, Frame Shift Ins 1, Nonsense Mutation 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- JAK2 | c.2047A>G p.R683G | Missense Mutation (SNP) | VAF 20/194 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519721, COSV67572554, COSV67587550; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- ADHFE1 | c.314C>T p.T105M | Missense Mutation (SNP) | VAF 45/261 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.631); catalogued as rs762948149, COSV52556227; called by muse, mutect2, varscan2
- ASTN2 | c.2434G>A p.D812N (on ENST00000313400 / NM_001365069.1; = p.D761N on NM_014010.5) | Missense Mutation (SNP) | VAF 38/374 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV57787714; called by muse, mutect2, varscan2
- CSMD3 | c.10213G>A p.E3405K (on ENST00000297405 / NM_001363185.1; = p.E3236K on NM_052900.3) | Missense Mutation (SNP) | VAF 59/351 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.338); catalogued as COSV52164185; called by muse, mutect2, varscan2
- DSE | c.1636A>G p.N546D | Missense Mutation (SNP) | VAF 75/441 reads (17%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs1460852754; called by muse, mutect2, varscan2
- EXOC4 | c.62C>T p.S21L | Missense Mutation (SNP) | VAF 60/373 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as rs183280115, COSV54081769, COSV99555488; called by muse, mutect2, varscan2
- FAM131A | c.976G>A p.D326N (on ENST00000310585; = p.D357N on NM_144635.5) | Missense Mutation (SNP) | VAF 60/317 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); catalogued as rs1379164109; called by muse, mutect2, varscan2
- NHLRC1 | c.91G>C p.E31Q | Missense Mutation (SNP) | VAF 114/700 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV61481288; called by muse, mutect2, varscan2
- SPEG | c.9133C>T p.R3045W | Missense Mutation (SNP) | VAF 143/386 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs769212993; called by muse, mutect2, varscan2
- UBA2 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 147/396 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.957); catalogued as COSV99875133; called by muse, mutect2, varscan2
- ZBTB47 | c.802C>T p.R268W | Missense Mutation (SNP) | VAF 239/560 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); catalogued as rs762192166; called by muse, varscan2
- ELAC2 | c.1846A>G p.I616V | Missense Mutation (SNP) | VAF 26/546 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- FAT1 | c.6993T>A p.D2331E | Missense Mutation (SNP) | VAF 75/341 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- LCOR | c.2107C>T p.Q703* | Nonsense Mutation (SNP) | VAF 45/306 reads (15%) | called by muse, mutect2, varscan2
- MAP2K3 | c.708C>G p.I236M (on ENST00000342679 / NM_145109.3; = p.I207M on NM_002756.4) | Missense Mutation (SNP) | VAF 49/594 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- PAX5 | c.279dup p.K94Qfs*8 | Frame Shift Ins (INS) | VAF 163/523 reads (31%) | called by mutect2, pindel, varscan2
- WDR3 | c.966G>A p.M322I | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANK3 | c.8805G>C p.V2935= | Silent (SNP) | VAF 93/254 reads (37%) | catalogued as COSV55081148; called by muse, mutect2, varscan2
- FILIP1 | c.2433C>T p.S811= | Silent (SNP) | VAF 153/412 reads (37%) | catalogued as rs761316787; called by muse, mutect2, varscan2
- NWD1 | c.3343A>C p.R1115= | Silent (SNP) | VAF 108/317 reads (34%) | called by muse, mutect2, varscan2
- P2RX5 | chr17:3672479 G>C | 3'Flank (SNP) | VAF 58/304 reads (19%) | called by muse, mutect2, varscan2
